Somatic mutation profile of tumor specimen TCGA-ZB-A963-01A (aliquot TCGA-ZB-A963-01A-11D-A428-09) from TCGA case TCGA-ZB-A963, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type AB, malignant; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 46.5 years (16,990 days).
Specimen TCGA-ZB-A963-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d0a1176-5006-41b4-9997-1bb6d7491ecd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZB-A963-10A (Blood Derived Normal), aliquot TCGA-ZB-A963-10A-01D-A42B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80babd3d-648a-4fc5-b8db-ffc3539db7f5

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 32/462 reads (7%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2
- ARMH4 | c.1196C>A p.T399N | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.731); called by muse, mutect2
- DDX58 | c.1789C>A p.L597I | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); called by muse, mutect2
- LRRC42 | c.971C>A p.P324Q | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLK4 | c.1565C>T p.T522I | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0); called by mutect2, varscan2
